EXCEPTIONAL_RESPONDERS case ER-B0GM — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/11fbf027-4ba6-4dcf-b40c-2e1bdfd7f8fd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1959; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 46.7 years (17,067 days); Year of diagnosis: 2006; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Days to last follow up: 4,192 days (11.5 years); Days to best overall response: 265 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Erlotinib; Days to treatment start: 111 days; Days to treatment end: 589 days (1.6 years).

Follow-up (1 entry)
- Days to follow up: 4,192 days (11.5 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 1,239 days (3.4 years); Days progression-free: 4,192 days (11.5 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0GM-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0GM-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 3; Percent tumor nuclei: 5; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 17; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-B0GM-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0GM-TTM2-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 5.
